Somatic mutation profile of tumor specimen TARGET-20-PASCGC-04A (aliquot TARGET-20-PASCGC-04A-01D) from TARGET case TARGET-20-PASCGC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,255 days).
Specimen TARGET-20-PASCGC-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d23828c8-ad3e-4e83-9277-58e91cf64d11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASCGC-10A (Blood Derived Normal), aliquot TARGET-20-PASCGC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35c01106-4446-4cd0-986c-ab7b9850d233

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 27, Silent 14, Nonsense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 152/376 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RPS6KA3 | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 24/340 reads (7%) | catalogued as rs1085307639; ClinVar: pathogenic; called by muse, mutect2
- ACTRT2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.433); catalogued as rs749018428, COSV65759132; called by mutect2, varscan2
- BCL6B | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs773476333, COSV53427873; called by muse, mutect2, varscan2
- CEP120 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1255595388; called by muse, mutect2
- GPD1L | c.982T>C p.Y328H | Missense Mutation (SNP) | VAF 43/651 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.079); catalogued as rs1474113316; called by muse, mutect2
- GRIK2 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100024396, COSV59710691; called by muse, mutect2, varscan2
- IFT81 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 40/616 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs527626533, COSV54362465; called by muse, mutect2
- OR1L1 | c.155G>T p.G52V (on ENST00000373686; = p.G2V on NM_001005236.3) | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as rs770742411, COSV58935249; called by muse, mutect2
- ORC1 | c.2458A>T p.M820L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as rs747748571; called by mutect2, varscan2
- PDZD4 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs367722751, COSV51245296; called by muse, mutect2, varscan2
- PTH2R | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1426733078; called by muse, mutect2
- PTPRG | c.3509C>G p.A1170G | Missense Mutation (SNP) | VAF 52/668 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs767539324; called by muse, mutect2
- PYROXD2 | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV65331384; called by muse, mutect2
- SLC36A2 | c.818T>G p.I273S | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs759189877, COSV58863154; called by muse, mutect2
- TIMM17A | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs377072616; called by muse, mutect2
- TRIM44 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1200328013, COSV100194692; called by muse, mutect2, varscan2
- UTP20 | c.3684A>C p.E1228D | Missense Mutation (SNP) | VAF 44/596 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs762081637; called by muse, mutect2
- WDR6 | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs754192348; called by mutect2, varscan2
- WT1 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 78/106 reads (74%) | catalogued as CM971595, COSV60065297; called by muse, varscan2
- CLIP1 | c.2076G>A p.M692I (on ENST00000620786 / NM_001247997.1; = p.M681I on NM_002956.2) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DCAF1 | c.1907T>C p.I636T | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- FUS | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2
- GCNA | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.413); called by muse, mutect2
- IGHG3 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.055); called by muse, mutect2
- LYZL6 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2
- NT5E | c.423T>G p.S141R | Missense Mutation (SNP) | VAF 26/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUP98 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 40/546 reads (7%) | called by muse, mutect2
- PXDNL | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- RB1CC1 | c.3407G>C p.C1136S | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC22A13 | c.146_170del p.H49Pfs*6 | Frame Shift Del (DEL) | VAF 114/291 reads (39%) | called by mutect2, pindel, varscan2
- TMTC1 | c.2517T>A p.Y839* (on ENST00000539277 / NM_001193451.2; = p.Y731* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 22/433 reads (5%) | called by muse, mutect2
- BRD1 | c.1005G>A p.V335= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs141495604; called by mutect2, varscan2
- DENND4B | c.1170C>T p.P390= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV63411786; called by muse, mutect2
- DPP6 | c.1401G>A p.S467= (on ENST00000377770 / NM_001364500.2; = p.S405= on NM_001936.5) | Silent (SNP) | VAF 70/137 reads (51%) | catalogued as rs372941823; called by muse, mutect2, varscan2
- H6PD | c.1332C>T p.S444= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs770186803; called by mutect2, varscan2
- KIAA1549L | c.921C>T p.T307= (on ENST00000321505; = p.T604= on NM_012194.3) | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as rs547710120, COSV55771470, COSV99683389; called by muse, mutect2, varscan2
- MRTFA | c.2604G>A p.P868= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs754100449; called by muse, mutect2, varscan2
- RBM20 | c.1542A>G p.K514= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs1463897410; called by muse, mutect2
- RGS10 | c.342G>A p.P114= (on ENST00000369101; = p.P108= on NM_002925.3) | Silent (SNP) | VAF 134/312 reads (43%) | catalogued as rs374019254; called by muse, mutect2, varscan2
- SULT6B1 | c.141G>A p.A47= (on ENST00000535679 / NM_001367551.1; = p.A9= on NM_001032377.2) | Silent (SNP) | VAF 187/466 reads (40%) | catalogued as rs778510865, COSV99573394; called by muse, mutect2, varscan2
- SYP | c.333C>T p.A111= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs145613874, COSV54295841; called by muse, mutect2
- TSHZ3 | c.1497C>T p.D499= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TWNK | c.1521C>T p.V507= | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as rs1158746133, COSV99272138; called by muse, mutect2
- XK | c.339C>A p.G113= | Silent (SNP) | VAF 15/180 reads (8%) | called by muse, mutect2
- ZNF84 | c.618C>G p.L206= | Silent (SNP) | VAF 30/595 reads (5%) | called by muse, mutect2
